Gene-level copy-number profile of tumor specimen HCM-CSHL-1266-C20-06A from HCMI case HCM-CSHL-1266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 34.7 years (12,684 days).
Specimen HCM-CSHL-1266-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b6760e19-936a-468f-a75a-9fa8ee8c2c18.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1266-C20-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/4c179202-9188-41db-a38a-1a61be9f4cae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 932; copy number 2: 5,348; copy number 3: 16,998; copy number 4: 26,015; copy number 5: 4,033; copy number 6: 2,508; copy number 7: 1,727; copy number 8: 764; copy number 9: 9; copy number 12: 11.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–6): AC104164.2, MIR548BB.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–3): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr10:79,661,394–79,826,594, 1 gene (within-gene range 0–3): NUTM2B-AS1.
- chr10:79,703,227–79,827,602, 2 genes: NUTM2B, AL135925.1.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–5): RPS10P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–5): AL138808.1.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:57,548,838–57,942,304, 11 genes, copy number 12: RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16.
- chr8:12,087,396–12,099,536, 2 genes, copy number 9: RNA5SP253, DEFB108D.
- chr17:18,450,244–18,475,920, 1 gene, copy number 9 (within-gene range 7–9): KRT16P4.
- chr17:18,460,391–18,551,705, 6 genes, copy number 9 (within-gene range 4–9): TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
